Somatic mutation profile of tumor specimen PCProject_0031_T1_WES (aliquot PCProject_0031_T1_WES_1) from CMI case PCProject_0031, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.1 years (21,212 days).
Specimen PCProject_0031_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0557c84-a6ff-4752-88ce-648ce54dc59e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0031_SALIVA (Saliva), aliquot PCProject_0031_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22b49a51-93b2-41b9-997a-c9ec90385f5e

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Frame Shift Del 5, Splice Site 2, 5'Flank 1, 5'UTR 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HCST | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV99385572; called by muse, mutect2
- POU5F2 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV101232657; called by muse, mutect2, varscan2
- SLC4A10 | c.1719G>C p.L573F (on ENST00000446997 / NM_001354461.2; = p.L543F on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99766045; called by muse, mutect2, varscan2
- ZPBP2 | c.415G>A p.E139K (on ENST00000348931 / NM_199321.3; = p.E117K on NM_198844.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62375577; called by muse, varscan2
- AFAP1 | c.225+2T>C p.X75_splice | Splice Site (SNP) | VAF 8/54 reads (15%) | called by muse, varscan2
- AL121845.3 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- ARX | c.836C>A p.A279D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ASXL2 | c.914del p.L305Yfs*6 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by pindel, varscan2
- CAP1 | c.793del p.E265Rfs*7 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- CTNNA2 | c.1480_1486delinsTCCCAC p.R494Sfs*3 | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | called by pindel, varscan2*
- DNHD1 | c.4397G>A p.C1466Y | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FAM234B | c.7_15del p.T3_L5del | In Frame Del (DEL) | VAF 17/167 reads (10%) | called by mutect2, pindel, varscan2
- KCNJ11 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- KDM1A | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KDR | c.1374G>T p.W458C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- NPAS3 | c.2236C>G p.P746A (on ENST00000356141 / NM_001164749.2; = p.P714A on NM_022123.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); called by muse, mutect2
- POLA1 | c.2153C>A p.T718N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.192); called by mutect2, varscan2
- RBBP8NL | c.62-5_79del p.X21_splice | Splice Site (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- SDK1 | c.1868G>C p.R623T | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- SMIM24 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- THSD4 | c.2119T>A p.Y707N | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2
- TP53 | c.778_779del p.S260Qfs*3 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- TTLL9 | c.197A>G p.E66G | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- UBR1 | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- YTHDC2 | c.3491_3492del p.E1164Afs*33 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by pindel*, varscan2
- CRHBP | c.765C>T p.S255= | Silent (SNP) | VAF 9/78 reads (12%) | called by muse, varscan2
- GRIK3 | c.2712C>T p.G904= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- KRT25 | c.1071C>T p.T357= | Silent (SNP) | VAF 25/204 reads (12%) | catalogued as rs923237946, COSV56447069; called by muse, mutect2, varscan2
- TCHHL1 | c.2055C>A p.S685= | Silent (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- VPS52 | c.1428A>G p.L476= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs1439477510; called by muse, mutect2, varscan2
- ZC3HAV1 | c.315A>G p.L105= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs767303733; called by muse, mutect2, varscan2
- EMX1 | chr2:72916837 C>T | 5'Flank (SNP) | VAF 9/92 reads (10%) | catalogued as rs1165026167; called by muse, mutect2, varscan2
- NET1 | c.-55C>G | 5'UTR (SNP) | VAF 7/40 reads (18%) | catalogued as rs996901459; called by muse, mutect2, varscan2
